Somatic mutation profile of tumor specimen C3N-02261-01 (aliquot CPT0381550009) from CPTAC case C3N-02261, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 57.1 years (20,860 days).
Specimen C3N-02261-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74fe49d9-993f-4416-a3bf-f613b90cdcb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02261-31 (Blood Derived Normal), aliquot CPT0381730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5bd614a-2d4b-4093-8f9e-b566c0b45361

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP36 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV52264412; called by muse, mutect2, varscan2
- DNMT3A | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV53071870; called by muse, mutect2, varscan2
- OR4S1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs545552726; called by muse, mutect2, varscan2
- PTDSS1 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV61264429; called by muse, mutect2, varscan2
- SHROOM4 | c.3935A>C p.Q1312P | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV56786170; called by muse, mutect2, varscan2
- TSPAN12 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 131/237 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.366); catalogued as rs143445702; called by muse, mutect2, varscan2
- UPF3A | c.1006A>T p.T336S | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs745825993; called by muse, mutect2, varscan2
- DDX46 | c.2330G>A p.G777E | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- DGAT2L6 | c.623T>A p.F208Y | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMD | c.4651C>A p.H1551N | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GPAA1 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); called by muse, mutect2
- MCM4 | c.1915_1916del p.T639Ffs*6 | Frame Shift Del (DEL) | VAF 22/158 reads (14%) | called by mutect2, pindel, varscan2
- MYF5 | c.339C>A p.N113K | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYPN | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- RNF207 | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 53/301 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SCN10A | c.2108T>C p.V703A | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- ZNF711 | c.926G>T p.R309I | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CEMIP2 | c.102A>T p.P34= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- MGAT5B | c.642G>A p.R214= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as COSV56926729; called by muse, mutect2, varscan2
- RNF216 | c.2412C>T p.H804= (on ENST00000425013 / NM_207116.3; = p.H861= on NM_207111.4) | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- CFL2 | c.*1771G>A | 3'UTR (SNP) | VAF 26/243 reads (11%) | called by muse, mutect2, varscan2
